Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4349, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4349-01A (Primary Tumor).

[page 1 of 2]
.....

Clinical Diagnosis & History:

with incidental left renal mass. Increasing in size past

Specimens Submitted:

1: SP: Kidney, left lower pole, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, left lower pole, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.5 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

[page 2 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

*** [REDACTED] [REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh labeled, "Left lower pole partial nephrectomy" and consists of a resected, unoriented segment of renal tissue measuring 4.5 x 2.5 x 2.2 cm. The perirenal fat is inked in black. The specimen is opened to reveal a circumscribed yellow-tan glistening, homogeneous mass 1.5 x 1.5 x 1.2 cm. The mass grossly abuts the renal capsule. Further sectioning reveals diffuse areas of hemorrhage and fibrosis. The remaining renal parenchyma is unremarkable glistening brown-tan. A sample of the tumor is submitted for [REDACTED] Representative sections submitted.

Summary of sections:

TC-tumor with black inked capsule

T-represent sectioning of tumor with adjacent unremarkable renal parenchyma

Summary of Sections:

Part 1: SP: Kidney, left lower pole, partial nephrectomy [REDACTED]

Block	Sect. Site	PCs
3	t	3
3	tc	3

Source: NCI Genomic Data Commons file fd5a610f-5caf-4573-8443-eedecf210953 (TCGA-BP-4349.C4DFD356-3EB6-404D-BEB1-0FA7647B60A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).